HCMI case HCM-BROD-0254-C49 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/300223b2-7479-4849-8de5-14b30c586c3a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 2004; Vital status: Dead; Days to death: 487 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (3)
1. Alveolar rhabdomyosarcoma (the primary disease): ICD-O-3 morphology code: 8920/3; ICD-10 code: C49.9; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Classification of tumor: primary; Age at diagnosis: 11.9 years (4,358 days); Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: Yes; Sites of involvement: Bone, NOS / Bone marrow / Abdomen.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Dactinomycin + Irinotecan + Vincristine; Treatment intent type: Neoadjuvant; Regimen or line of therapy: VAC/VI; Days to treatment start: 275 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Gemcitabine Hydrochloride + Vinorelbine Tartrate; Treatment intent type: Neoadjuvant; Days to treatment start: 275 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Temsirolimus; Treatment intent type: Neoadjuvant; Days to treatment start: 334 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Gemcitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 440 days (1.2 years); Days to treatment end: 487 days (1.3 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 440 days (1.2 years); Days to treatment end: 441 days (1.2 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Neoadjuvant.
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/6; ICD-10 code: C78.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 13.1 years (4,785 days); Days to diagnosis: 427 days (1.2 years); Cog rhabdomyosarcoma risk group: High Risk; Irs group: Group IV.
   Pathology details: Tumor largest dimension diameter: 9 cm.
3. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/6; ICD-10 code: C78.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 13.3 years (4,845 days); Days to diagnosis: 487 days (1.3 years); Cog rhabdomyosarcoma risk group: High Risk; Irs group: Group IV; Tumor confined to organ of origin: No.
   Pathology details: Tumor largest dimension diameter: 9 cm.

Follow-up (4 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Days to progression: 0 days.
- Days to follow up: 487 days (1.3 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- FOXO1 translocation: Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 17.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (5 samples)
- Sample HCM-BROD-0254-C49-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-BROD-0254-C49-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 11.
- Sample HCM-BROD-0254-C49-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
- Sample HCM-BROD-0254-C49-86M: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 17.
- Sample HCM-BROD-0254-C49-86N: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 15.
